Somatic mutation profile of tumor specimen BLGSP-71-08-00021-01A (aliquot BLGSP-71-08-00021-01A-01D-A663-33) from CGCI case BLGSP-71-08-00021, project CGCI-BLGSP (Burkitt Lymphoma Genome Sequencing Project). Sex at birth: male; Vital status: Alive; Primary diagnosis: Burkitt lymphoma, NOS (Includes all variants); Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 6.9 years (2,531 days).
Specimen BLGSP-71-08-00021-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Maxilla; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 52806d49-8a50-47e4-9bbc-73f741099726.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BLGSP-71-08-00021-10A (Blood Derived Normal), aliquot BLGSP-71-08-00021-10A-01D-A663-33; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a8df43d0-9870-4ed7-a533-a7474ae68667

The open-access MAF lists 7 somatic variants for this specimen: 5 protein-altering or splice-affecting, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, 5'UTR 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.488A>G p.Y163C | Missense Mutation (SNP) | VAF 13/33 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs148924904, CM942135, COSV52663142, COSV52676381; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- BCL6 | c.1760C>A p.A587D | Missense Mutation (SNP) | VAF 113/250 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.209); catalogued as COSV51650170; called by muse, mutect2, varscan2
- MYC | c.413T>G p.F138C (on ENST00000377970; = p.F153C on NM_002467.6) | Missense Mutation (SNP) | VAF 35/124 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52368798, COSV52375241; called by muse, mutect2, varscan2
- LRP1B | c.7997G>T p.G2666V | Missense Mutation (SNP) | VAF 110/253 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SMARCA4 | c.3725A>G p.E1242G | Missense Mutation (SNP) | VAF 5/98 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.005); called by muse, mutect2
- MYC | c.-176G>A | 5'UTR (SNP) | VAF 43/79 reads (54%) | called by muse, mutect2, varscan2
- MYC | c.-106A>T | 5'UTR (SNP) | VAF 54/118 reads (46%) | called by muse, mutect2
